Somatic mutation profile of tumor specimen ALCH-B1QJ-TTP1-A (aliquot ALCH-B1QJ-TTP1-A-1-0-D-A76C-36) from ALCHEMIST case ALCH-B1QJ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 67.7 years (24,725 days).
Specimen ALCH-B1QJ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a613bd9-19c9-4606-9423-9d9f8c566fd3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1QJ-NB1-A (Blood Derived Normal), aliquot ALCH-B1QJ-NB1-A-1-0-D-A76C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3de476d-2c99-4ba2-869a-7ed965ac4900

The open-access MAF lists 919 somatic variants for this specimen: 624 protein-altering or splice-affecting, 191 silent, 104 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 543, Silent 191, Nonsense Mutation 48, Intron 39, RNA 26, 3'UTR 16, Frame Shift Del 13, 5'UTR 12, Splice Site 10, 5'Flank 9, Splice Region 5, Frame Shift Ins 3.

Variants (750 of 919; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 96/741 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC26A4 | c.2186T>C p.L729P | Missense Mutation (SNP) | VAF 68/816 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1045933779, CM138620; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.542G>C p.R181P | Missense Mutation (SNP) | VAF 46/396 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as CM056067, CM920671, CM942120, COSV52675795, COSV52676870, COSV52730435, COSV53567603; called by muse, mutect2, varscan2
- ABCA3 | c.4688C>T p.S1563F | Missense Mutation (SNP) | VAF 16/252 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV57049651; called by muse, mutect2
- ABCA6 | c.2420C>A p.S807* | Nonsense Mutation (SNP) | VAF 14/284 reads (5%) | catalogued as COSV52637611; called by muse, mutect2
- ABCB1 | c.3835C>T p.R1279C | Missense Mutation (SNP) | VAF 85/891 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs137996914, COSV99711994; called by muse, mutect2
- ABCC11 | c.2272G>T p.A758S | Missense Mutation (SNP) | VAF 37/589 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.017); catalogued as rs752306615; called by muse, mutect2
- ADAM18 | c.1965C>A p.F655L | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV55843213; called by muse, mutect2
- ADCY4 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 62/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60258900; called by muse, mutect2, varscan2
- ADGRB3 | c.3335C>A p.T1112K | Missense Mutation (SNP) | VAF 49/342 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV99486331; called by muse, mutect2, varscan2
- ADGRL3 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 19/432 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.157); catalogued as COSV101547380; called by muse, mutect2
- ADGRL3 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 18/421 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1366742438; called by muse, mutect2
- AGAP1 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 26/480 reads (5%) | catalogued as COSV58335278; called by muse, mutect2
- ANGPTL5 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 29/558 reads (5%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.449); catalogued as rs1240985011; called by muse, mutect2
- ANKFN1 | c.2827G>C p.E943Q (on ENST00000653862; = p.E796Q on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/487 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV73720115; called by muse, mutect2
- ANXA6 | c.1518G>T p.T506= | Splice Region (SNP) | VAF 45/409 reads (11%) | catalogued as COSV62907323; called by muse, mutect2, varscan2
- ASTN2 | c.1105C>G p.Q369E | Missense Mutation (SNP) | VAF 63/495 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV100525539; called by muse, mutect2, varscan2
- ATP13A3 | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 42/568 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99757703; called by muse, mutect2
- BANK1 | c.1897C>G p.Q633E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1327583999, COSV59842879; called by muse, mutect2
- BRD2 | c.2053G>T p.E685* | Nonsense Mutation (SNP) | VAF 46/859 reads (5%) | catalogued as COSV100875661; called by muse, mutect2
- BTBD7 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs1220607364; called by muse, mutect2
- BTG4 | c.285G>T p.W95C | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278468610; called by muse, mutect2, varscan2
- C1QB | c.313C>A p.P105T | Missense Mutation (SNP) | VAF 12/304 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.505); catalogued as COSV59245744; called by muse, mutect2
- CALN1 | c.22G>A p.A8T (on ENST00000329008 / NM_001017440.3; = p.A50T on NM_031468.4) | Missense Mutation (SNP) | VAF 32/276 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.041); catalogued as rs767526121, COSV61141568; called by muse, mutect2, varscan2
- CASKIN1 | c.2984C>A p.T995K | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58218269; called by muse, mutect2, varscan2
- CD22 | c.1945G>T p.V649L | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.096); catalogued as COSV50051066; called by muse, mutect2
- CDH8 | c.668C>A p.A223D | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV54881279; called by muse, mutect2
- CDK3 | c.299C>T p.P100L | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.491); catalogued as rs267605055; called by muse, mutect2, varscan2
- CEMIP | c.2971G>T p.D991Y | Missense Mutation (SNP) | VAF 45/266 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99586282; called by muse, mutect2, varscan2
- CEP162 | c.45G>T p.Q15H | Missense Mutation (SNP) | VAF 22/188 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs867858310; called by muse, mutect2, varscan2
- CEP170 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as COSV100317323; called by muse, mutect2
- CES5A | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 53/852 reads (6%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.665); catalogued as COSV51869565; called by muse, mutect2
- CFAP46 | c.7861C>T p.P2621S | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as rs1450674442; called by muse, mutect2
- CFAP47 | c.8770G>T p.G2924* | Nonsense Mutation (SNP) | VAF 28/286 reads (10%) | catalogued as COSV66216620; called by muse, mutect2
- CGA | c.156C>A p.C52* | Nonsense Mutation (SNP) | VAF 24/313 reads (8%) | catalogued as COSV63644158; called by muse, mutect2
- CHL1 | c.1855C>A p.H619N (on ENST00000397491 / NM_001253387.1; = p.H635N on NM_006614.4) | Missense Mutation (SNP) | VAF 41/387 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs1477183921; called by muse, mutect2
- CLCN1 | c.2788C>G p.P930A | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100577836; called by muse, mutect2, varscan2
- CLEC14A | c.23G>T p.C8F | Missense Mutation (SNP) | VAF 18/195 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.66); catalogued as COSV60562763; called by muse, mutect2
- CNOT10 | c.1055A>G p.N352S | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as rs1220769181; called by muse, mutect2, varscan2
- CNTNAP2 | c.217G>C p.G73R | Missense Mutation (SNP) | VAF 74/889 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62170695; called by muse, mutect2
- COBL | c.2523G>C p.M841I | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs905996299; called by muse, mutect2, varscan2
- COL22A1 | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 78/856 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs150078954; called by muse, mutect2
- COL3A1 | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 20/480 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1228569590; called by muse, mutect2
- COLEC10 | c.202G>T p.G68* | Nonsense Mutation (SNP) | VAF 56/555 reads (10%) | catalogued as COSV60521978; called by muse, mutect2, varscan2
- COX11 | c.786dup p.E263* | Frame Shift Ins (INS) | VAF 56/392 reads (14%) | catalogued as rs778099821; called by mutect2, varscan2
- COX8C | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/122 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1215556957; called by muse, mutect2, varscan2
- CPT1A | c.1340G>T p.R447L | Missense Mutation (SNP) | VAF 39/436 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV55762484; called by muse, mutect2
- CPXM2 | c.97C>A p.P33T | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.011); catalogued as COSV99057066; called by muse, mutect2
- CREB5 | c.655C>A p.P219T (on ENST00000357727 / NM_182898.4; = p.P212T on NM_004904.3) | Missense Mutation (SNP) | VAF 61/734 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as rs1245011461; called by muse, mutect2
- CSMD2 | c.3494G>A p.G1165E | Missense Mutation (SNP) | VAF 37/681 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53883818; called by muse, mutect2
- CSMD3 | c.6538C>T p.R2180W (on ENST00000297405 / NM_001363185.1; = p.R2076W on NM_052900.3) | Missense Mutation (SNP) | VAF 112/848 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as rs747470179, COSV52126522; called by muse, mutect2, varscan2
- CSMD3 | c.3244G>C p.G1082R (on ENST00000297405 / NM_001363185.1; = p.G978R on NM_052900.3) | Missense Mutation (SNP) | VAF 89/997 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV52253851; called by muse, mutect2
- CTTN | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 41/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200865893, COSV100096929, COSV100097710; called by muse, mutect2, varscan2
- CYP11B1 | c.1070A>G p.K357R | Missense Mutation (SNP) | VAF 40/423 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52828934; called by muse, mutect2
- CYP11B1 | c.945C>A p.S315R | Missense Mutation (SNP) | VAF 66/546 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs372647044, COSV52825624; called by muse, mutect2, varscan2
- CYP11B1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 84/780 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as CM160921; called by mutect2, varscan2
- CYP4F22 | c.70G>T p.V24L | Missense Mutation (SNP) | VAF 64/674 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99512505; called by muse, mutect2
- DCLK3 | c.810C>A p.S270R | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.075); catalogued as rs746567549; called by muse, mutect2, varscan2
- DCP1A | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 17/133 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as COSV99587718; called by muse, mutect2, varscan2
- DLL1 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs752399003; called by muse, mutect2
- DPYSL4 | c.1399C>A p.R467S | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV53840165; called by muse, mutect2
- DSCAM | c.5703del p.L1901Ffs*11 | Frame Shift Del (DEL) | VAF 7/56 reads (13%) | catalogued as COSV68024669; called by mutect2, pindel*, varscan2
- DSG3 | c.1949G>C p.G650A | Missense Mutation (SNP) | VAF 104/816 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV57128159; called by muse, mutect2, varscan2
- DTNA | c.1422G>T p.Q474H | Missense Mutation (SNP) | VAF 88/842 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52013315; called by muse, mutect2
- ECT2L | c.1321G>T p.G441* | Nonsense Mutation (SNP) | VAF 15/202 reads (7%) | catalogued as COSV62887207; called by muse, mutect2
- EFCAB7 | c.1330G>T p.A444S | Missense Mutation (SNP) | VAF 36/529 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV100937564; called by muse, mutect2
- ERICH3 | c.2393G>A p.W798* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs894706041; called by muse, mutect2
- FAM71D | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 14/253 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV100315123; called by muse, mutect2
- FAT3 | c.8630C>A p.T2877N | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53195885; called by muse, mutect2
- FGF21 | c.458A>C p.H153P | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1315553668; called by muse, mutect2
- FHDC1 | c.2865G>T p.Q955H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV52602792; called by muse, mutect2, varscan2
- FIG4 | c.2459+1G>T p.X820_splice | Splice Site (SNP) | VAF 60/539 reads (11%) | catalogued as CS1411823; called by muse, mutect2, varscan2
- FLG | c.7091G>T p.S2364I | Missense Mutation (SNP) | VAF 70/1177 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs765712653; called by muse, mutect2
- FLG | c.464G>T p.S155I | Missense Mutation (SNP) | VAF 88/1010 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as COSV64247087; called by muse, mutect2
- FLT1 | c.3227A>G p.Y1076C | Missense Mutation (SNP) | VAF 40/652 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1325577961; called by muse, mutect2
- FLT1 | c.2878G>A p.V960I | Missense Mutation (SNP) | VAF 50/704 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as rs554058758, COSV56725597; called by muse, mutect2
- FSBP | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 87/544 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as COSV99890897; called by muse, mutect2, varscan2
- GAB4 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV68754759; called by muse, mutect2
- GABRR1 | c.1258C>A p.P420T | Missense Mutation (SNP) | VAF 122/1234 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV65619162; called by muse, mutect2
- GIGYF2 | c.3158C>G p.P1053R | Missense Mutation (SNP) | VAF 40/380 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as rs746427143, COSV101004365; called by muse, mutect2, varscan2
- GRB14 | c.613C>A p.P205T | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55736756; called by muse, mutect2
- GRIN2A | c.1708G>T p.A570S | Missense Mutation (SNP) | VAF 56/1060 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100409433; called by muse, mutect2
- GRIN3A | c.1061G>T p.W354L | Missense Mutation (SNP) | VAF 35/277 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV62454319; called by muse, mutect2, varscan2
- GRK4 | c.203G>T p.R68M (on ENST00000398052 / NM_182982.3; = p.R36M on NM_005307.3) | Missense Mutation (SNP) | VAF 50/444 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902601191; called by muse, mutect2, varscan2
- GRM8 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 47/482 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100283399, COSV58880646; called by muse, mutect2, varscan2
- HIF3A | c.27G>T p.R9S (on ENST00000377670 / NM_152795.4; = p.R7S on NM_152794.4) | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs778626472; called by muse, mutect2, varscan2
- HIVEP2 | c.6593G>T p.G2198V | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV50009470; called by muse, mutect2
- HJURP | c.2173G>T p.G725* | Nonsense Mutation (SNP) | VAF 26/268 reads (10%) | catalogued as rs1489559922; called by muse, mutect2
- HOXC12 | c.752T>A p.L251* | Nonsense Mutation (SNP) | VAF 82/575 reads (14%) | catalogued as COSV54534649; called by muse, mutect2, varscan2
- HSPA1L | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1290081406, COSV65148942; called by muse, mutect2
- IBTK | c.229G>T p.D77Y | Missense Mutation (SNP) | VAF 62/639 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1301382749; called by muse, mutect2
- IKZF1 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 24/531 reads (5%) | catalogued as COSV58793123; called by muse, mutect2
- IL1R1 | c.391A>G p.K131E | Missense Mutation (SNP) | VAF 43/337 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.062); catalogued as COSV99292846; called by muse, mutect2, varscan2
- ILDR2 | c.108G>T p.Q36H | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54832048; called by muse, mutect2, varscan2
- ILRUN | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 20/318 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.301); catalogued as COSV64990431; called by muse, mutect2
- IQSEC1 | c.2024G>A p.R675Q | Missense Mutation (SNP) | VAF 42/326 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs750405546; called by muse, mutect2, varscan2
- IRS4 | c.3143T>C p.V1048A | Missense Mutation (SNP) | VAF 30/130 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as COSV100929875; called by muse, mutect2, varscan2
- KCNH7 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 27/339 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs373376905; called by muse, mutect2
- KCNMA1 | c.1123G>C p.G375R | Missense Mutation (SNP) | VAF 81/1332 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99695945; called by muse, mutect2
- KCNN3 | c.1063C>T p.R355W | Missense Mutation (SNP) | VAF 28/270 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769288919, COSV55211748; called by muse, varscan2
- KEAP1 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 80/690 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as COSV50260624; called by muse, mutect2, varscan2
- KHK | c.447G>T p.M149I | Missense Mutation (SNP) | VAF 75/729 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99565378; called by muse, mutect2, varscan2
- LAMC1 | c.4212G>C p.K1404N | Missense Mutation (SNP) | VAF 91/833 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV51151217; called by muse, mutect2, varscan2
- LBP | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 15/348 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1324739679; called by muse, mutect2
- LRP1B | c.12107C>A p.P4036H | Missense Mutation (SNP) | VAF 45/384 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67208018; called by muse, mutect2
- LRP1B | c.11188C>A p.L3730I | Missense Mutation (SNP) | VAF 39/724 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.967); catalogued as COSV101255797, COSV101260540; called by muse, mutect2
- LRRC4C | c.750G>C p.M250I | Missense Mutation (SNP) | VAF 35/330 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV53423667; called by muse, mutect2, varscan2
- LTBP1 | c.3115G>A p.V1039M (on ENST00000404816 / NM_206943.4; = p.V713M on NM_000627.4) | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs1214274039; called by muse, mutect2
- LY6L | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.029); catalogued as rs1383592415; called by muse, mutect2
- MAGEB6 | c.937C>A p.L313M | Missense Mutation (SNP) | VAF 28/266 reads (11%) | SIFT tolerated (0.73); PolyPhen benign (0.009); catalogued as COSV100983753; called by muse, mutect2, varscan2
- MAP2 | c.3197G>T p.R1066M | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV52286134; called by muse, mutect2, varscan2
- MBOAT1 | c.1465A>G p.I489V | Missense Mutation (SNP) | VAF 54/412 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1299552892; called by muse, varscan2
- MED12L | c.4790G>T p.R1597L | Missense Mutation (SNP) | VAF 34/324 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56393102; called by muse, mutect2, varscan2
- MGRN1 | c.1423G>T p.D475Y | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as rs1002578311; called by muse, mutect2
- MMRN1 | c.2321C>A p.T774K | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.109); catalogued as rs1332644223; called by muse, mutect2
- MPPED2 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 68/804 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100813111, COSV63901358; called by muse, mutect2
- MS4A5 | c.562G>T p.G188W | Missense Mutation (SNP) | VAF 49/496 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV99038292; called by muse, varscan2
- MUC15 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 43/431 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as COSV55556539; called by muse, mutect2
- MYH7 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 64/708 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs730880841, CM132331; called by muse, mutect2
- MYOF | c.3218G>T p.R1073L | Missense Mutation (SNP) | VAF 81/950 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100825559; called by muse, mutect2
- NDN | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.029); catalogued as rs1308499928; called by muse, mutect2
- NEK1 | c.323G>T p.W108L | Missense Mutation (SNP) | VAF 13/245 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1469219144; called by muse, mutect2
- NETO1 | c.841C>A p.Q281K | Missense Mutation (SNP) | VAF 55/536 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV55001496; called by muse, mutect2, varscan2
- NHS | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs1475721202; called by muse, mutect2, varscan2
- NHSL2 | c.913G>T p.G305C (on ENST00000510661; = p.G671C on NM_001013627.2) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101030201; called by muse, mutect2, varscan2
- NLRP3 | c.508C>A p.R170S | Missense Mutation (SNP) | VAF 44/770 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60228728; called by muse, mutect2
- NLRP5 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 31/237 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1292394589; called by muse, mutect2, varscan2
- NPAP1 | c.2699C>A p.T900K | Missense Mutation (SNP) | VAF 45/549 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV61508437; called by muse, mutect2
- NPAS4 | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.63); catalogued as rs1414845426; called by muse, mutect2
- NR5A1 | c.451G>T p.G151C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.195); catalogued as COSV65294628, COSV65294921; called by muse, mutect2, varscan2
- NRAP | c.2252A>G p.Y751C (on ENST00000359988 / NM_001322945.2; = p.Y716C on NM_006175.4) | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63491765; called by muse, mutect2, varscan2
- NRK | c.2611-1G>T p.X871_splice | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV99687082; called by muse, mutect2, varscan2
- NRXN1 | c.3646C>A p.R1216S | Missense Mutation (SNP) | VAF 54/596 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV60488178; called by muse, mutect2
- OR14I1 | c.664A>G p.T222A | Missense Mutation (SNP) | VAF 50/458 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.163); catalogued as rs767476887; called by muse, mutect2
- OR2F2 | c.238C>A p.Q80K | Missense Mutation (SNP) | VAF 56/382 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV68832898; called by muse, mutect2, varscan2
- OR2G6 | c.571G>T p.D191Y | Missense Mutation (SNP) | VAF 36/365 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100598180, COSV58576244; called by muse, mutect2
- OR2L8 | c.123C>A p.N41K | Missense Mutation (SNP) | VAF 34/587 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.356); catalogued as COSV61728616; called by muse, mutect2
- OR2W3 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 38/416 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV64456290; called by muse, mutect2
- OR2W3 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as COSV100831811; called by muse, mutect2
- OR52B4 | c.136C>A p.L46M | Missense Mutation (SNP) | VAF 40/482 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV68768965; called by muse, mutect2
- OR56A1 | c.789G>C p.L263F | Missense Mutation (SNP) | VAF 37/317 reads (12%) | SIFT tolerated (0.53); PolyPhen benign (0.042); catalogued as COSV57364083; called by muse, mutect2, varscan2
- OR6B1 | c.256T>C p.W86R | Missense Mutation (SNP) | VAF 28/245 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV68770566; called by muse, mutect2, varscan2
- OR6N1 | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 24/242 reads (10%) | catalogued as COSV58650186; called by muse, mutect2
- OR8K5 | c.93C>G p.F31L | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.04); catalogued as COSV57887949; called by muse, mutect2
- OS9 | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 68/800 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV57783678; called by muse, mutect2
- OSBPL7 | c.2451G>T p.W817C | Missense Mutation (SNP) | VAF 15/395 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); catalogued as rs1469410475; called by muse, mutect2
- OTOG | c.7108C>A p.P2370T | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV61129972; called by muse, mutect2
- PCDH15 | c.2891G>A p.R964K | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs149605588; ClinVar: uncertain significance; called by muse, mutect2
- PCDH17 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 30/561 reads (5%) | catalogued as COSV64979583; called by muse, mutect2
- PCDHA1 | c.2332C>T p.P778S | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); catalogued as COSV65373400; called by muse, mutect2
- PCDHA11 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 62/435 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs372502721, COSV56508035; called by muse, mutect2, varscan2
- PCDHB11 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 96/594 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as rs1241481309; called by muse, mutect2, varscan2
- PCLO | c.2875G>T p.G959* | Nonsense Mutation (SNP) | VAF 38/420 reads (9%) | catalogued as COSV61632555; called by muse, mutect2
- PHF20L1 | c.508-4G>T | Splice Region (SNP) | VAF 48/364 reads (13%) | catalogued as COSV55194066; called by muse, mutect2, varscan2
- PIK3CG | c.225G>T p.W75C | Missense Mutation (SNP) | VAF 24/174 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.009); catalogued as rs1368134057, COSV63255504; called by muse, mutect2, varscan2
- PKD1L1 | c.8068C>A p.L2690M | Missense Mutation (SNP) | VAF 70/1076 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.888); catalogued as COSV51841734; called by muse, mutect2
- PLA2G7 | c.146C>A p.A49E | Missense Mutation (SNP) | VAF 74/794 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.598); catalogued as rs1295335831; called by muse, mutect2
- PLEKHA5 | c.508G>T p.V170F | Missense Mutation (SNP) | VAF 74/531 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54700573; called by mutect2, varscan2
- PLXNA4 | c.605G>T p.R202L | Missense Mutation (SNP) | VAF 92/634 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58141798; called by muse, mutect2, varscan2
- POLQ | c.2170G>T p.V724L | Missense Mutation (SNP) | VAF 63/712 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV51763389; called by muse, mutect2
- POM121L12 | c.544C>T p.L182F | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101374966, COSV68694803; called by muse, mutect2
- PRAME | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.072); catalogued as COSV67161850; called by muse, mutect2
- PRB4 | c.328T>A p.S110T | Missense Mutation (SNP) | VAF 37/296 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.026); catalogued as COSV54394911; called by muse, varscan2
- PRDM9 | c.709C>A p.R237S | Missense Mutation (SNP) | VAF 52/903 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1187228739, COSV99689805, COSV99689896; called by muse, mutect2
- PRR23B | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); catalogued as COSV61495223; called by muse, mutect2, varscan2
- PRR32 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 45/635 reads (7%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs752831115; called by muse, mutect2
- PTPRN2 | c.1493G>A p.G498D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.093); catalogued as COSV101235231; called by muse, mutect2
- RBM47 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs1276411416; called by muse, mutect2, varscan2
- RGL4 | c.259C>T p.R87W | Missense Mutation (SNP) | VAF 32/558 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs146983963; called by muse, mutect2
- RNASET2 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 52/594 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.479); catalogued as COSV50351301; called by muse, mutect2
- RNF213 | c.14587G>T p.D4863Y | Missense Mutation (SNP) | VAF 76/515 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as CM116647; called by muse, mutect2, varscan2
- ROBO4 | c.1695G>A p.W565* | Nonsense Mutation (SNP) | VAF 58/474 reads (12%) | catalogued as COSV60621904; called by muse, mutect2, varscan2
- RTKN2 | c.1495G>T p.G499W | Missense Mutation (SNP) | VAF 23/281 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs1422467494; called by muse, mutect2
- SH2D4B | c.206A>C p.Q69P | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs757755610; called by muse, mutect2
- SHC1 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV58315725; called by muse, mutect2
- SIPA1L2 | c.3069G>T p.Q1023H | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV53395924; called by muse, mutect2
- SLC17A6 | c.1708C>A p.Q570K | Missense Mutation (SNP) | VAF 21/186 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs778273031; called by muse, varscan2
- SLC18A2 | c.191G>T p.R64M | Missense Mutation (SNP) | VAF 36/447 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV100042256; called by muse, mutect2
- SLC8A3 | c.1139C>A p.A380D | Missense Mutation (SNP) | VAF 42/590 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV63522744; called by muse, mutect2
- SMTN | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 24/353 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV60780919; called by muse, mutect2
- SOCS6 | c.274G>T p.G92C | Missense Mutation (SNP) | VAF 56/435 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.525); catalogued as COSV67547076; called by muse, mutect2, varscan2
- SPEG | c.7204G>C p.E2402Q | Missense Mutation (SNP) | VAF 29/334 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.034); catalogued as rs1246549122; called by muse, mutect2
- SPRY1 | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 52/1180 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1292973248, COSV100201947; called by muse, mutect2
- SPTA1 | c.2413G>A p.E805K | Missense Mutation (SNP) | VAF 78/691 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032959692, COSV63757823; called by muse, mutect2, varscan2
- SYNE2 | c.7654G>T p.D2552Y | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1194848697; called by muse, mutect2
- SYNPO | c.2702G>T p.R901L (on ENST00000394243 / NM_001166208.2; = p.R657L on NM_007286.6) | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100302478; called by muse, mutect2, varscan2
- TACR2 | c.188G>T p.R63M | Missense Mutation (SNP) | VAF 32/359 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64822569; called by muse, mutect2
- TBX3 | c.960G>T p.Q320H (on ENST00000257566 / NM_016569.4; = p.Q300H on NM_005996.4) | Missense Mutation (SNP) | VAF 123/1002 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV57476230; called by muse, mutect2, varscan2
- TDRD6 | c.1715G>C p.R572P | Missense Mutation (SNP) | VAF 28/522 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60177599; called by muse, mutect2
- TIAM2 | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 26/315 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as rs767646643; called by muse, mutect2
- TLK1 | c.406G>T p.G136* | Nonsense Mutation (SNP) | VAF 52/467 reads (11%) | catalogued as COSV62633638; called by muse, mutect2, varscan2
- TLN2 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 45/531 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1343670062; called by muse, mutect2
- TMA16 | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 26/305 reads (9%) | catalogued as COSV62187303; called by muse, mutect2
- TMTC4 | c.1699G>C p.E567Q (on ENST00000376234 / NM_001350577.2; = p.E586Q on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/625 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as COSV60893841; called by muse, mutect2
- TNFRSF11A | c.577G>T p.V193F | Missense Mutation (SNP) | VAF 91/1022 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54023423; called by muse, mutect2
- TNN | c.2530G>C p.G844R | Missense Mutation (SNP) | VAF 73/683 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.098); catalogued as COSV53427988, COSV99511933; called by muse, mutect2, varscan2
- TOP3A | c.1411A>G p.M471V | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs778063670, COSV58176986; called by muse, mutect2, varscan2
- TP53AIP1 | c.73G>T p.G25C | Missense Mutation (SNP) | VAF 20/277 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.93); catalogued as COSV71688863; called by muse, mutect2
- TSPYL6 | c.1130C>A p.P377Q | Missense Mutation (SNP) | VAF 16/417 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414324329; called by muse, mutect2
- TTN | c.10716G>T p.E3572D (on ENST00000591111; = p.E3526D on NM_003319.4) | Missense Mutation (SNP) | VAF 60/760 reads (8%) | catalogued as rs377423256; ClinVar: uncertain significance; called by muse, mutect2
- TTN | c.2729C>T p.T910I (on ENST00000591111; = p.T864I on NM_003319.4) | Missense Mutation (SNP) | VAF 64/760 reads (8%) | PolyPhen benign (0.013); catalogued as rs752722279; called by muse, mutect2
- UNC79 | c.1180G>C p.G394R (on ENST00000393151 / NM_001346218.2; = p.G217R on NM_020818.5) | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.408); catalogued as COSV56419229; called by muse, mutect2
- UPRT | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV64912625; called by muse, mutect2, varscan2
- UTRN | c.4510C>T p.Q1504* | Nonsense Mutation (SNP) | VAF 36/618 reads (6%) | catalogued as rs760400397; called by muse, mutect2
- WDFY4 | c.4006T>A p.C1336S | Missense Mutation (SNP) | VAF 92/713 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1369736249; called by muse, mutect2, varscan2
- WDR82 | c.544G>T p.G182W | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56602483; called by muse, mutect2, varscan2
- WDR90 | c.4929G>T p.W1643C | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV53466696; called by muse, mutect2, varscan2
- WNT2 | c.859del p.L287Wfs*10 | Frame Shift Del (DEL) | VAF 30/195 reads (15%) | catalogued as COSV55413255; called by mutect2, pindel, varscan2
- XIRP2 | c.6134C>A p.S2045Y (on ENST00000628543; = p.S2220Y on NM_152381.6) | Missense Mutation (SNP) | VAF 33/586 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV99744347; called by muse, mutect2
- YIPF7 | c.666G>T p.M222I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs759719745; called by muse, mutect2
- ZBBX | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV56785362; called by muse, mutect2, varscan2
- ZFPM2 | c.1521C>G p.I507M | Missense Mutation (SNP) | VAF 202/1058 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65875404; called by muse, mutect2, varscan2
- ZFYVE26 | c.6796C>T p.R2266W | Missense Mutation (SNP) | VAF 100/1076 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340491429, COSV61325830; called by muse, mutect2
- ZIC1 | c.1245C>A p.D415E | Missense Mutation (SNP) | VAF 52/609 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99291739; called by muse, mutect2
- ZMPSTE24 | c.1023G>T p.K341N | Missense Mutation (SNP) | VAF 40/430 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1163932861; called by muse, mutect2, varscan2
- ZMYM1 | c.1793G>T p.G598V | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as COSV63250980; called by muse, mutect2
- ZNF557 | c.70G>T p.V24F (on ENST00000414706 / NM_001044388.2; = p.V31F on NM_024341.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/385 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.047); catalogued as COSV53274919; called by muse, mutect2
- ZNF579 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.594); catalogued as rs1158376951; called by muse, mutect2, varscan2
- ZNF679 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 50/552 reads (9%) | catalogued as COSV55380507; called by muse, mutect2
- ZNF716 | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 22/358 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV70782673; called by muse, mutect2
- ZNF99 | c.2508G>T p.K836N | Missense Mutation (SNP) | VAF 39/421 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); catalogued as COSV99081412; called by muse, mutect2
- ZP4 | c.1175G>T p.G392V | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63911577; called by muse, mutect2
- AASS | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 85/635 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- AATK | c.3065G>T p.G1022V (on ENST00000326724 / NM_001080395.3; = p.G919V on NM_004920.2) | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.024); called by muse, mutect2
- ABCC8 | c.1066T>A p.Y356N | Missense Mutation (SNP) | VAF 68/564 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- ABCC8 | c.498G>C p.Q166H | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABI3BP | c.260-1G>T p.X87_splice | Splice Site (SNP) | VAF 32/408 reads (8%) | called by muse, mutect2
- ABRAXAS1 | c.970A>T p.T324S | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACOT12 | c.1249G>T p.D417Y | Missense Mutation (SNP) | VAF 37/265 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACTC1 | c.481G>T p.V161L | Missense Mutation (SNP) | VAF 60/728 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2
- ACTR5 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 27/686 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, mutect2
- ACTRT1 | c.846C>A p.S282R | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM29 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 16/342 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.022); called by muse, mutect2
- ADAM29 | c.1940T>G p.L647R | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.147); called by muse, mutect2
- ADAMTS2 | c.3247C>A p.P1083T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS7 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 45/225 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAMTS8 | c.1934G>T p.G645V | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.1898C>A p.A633E | Missense Mutation (SNP) | VAF 62/331 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ADGRB3 | c.3041G>T p.W1014L | Missense Mutation (SNP) | VAF 72/645 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- AEBP1 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 30/279 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALAS2 | c.1564C>A p.P522T | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH9A1 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 38/388 reads (10%) | called by muse, mutect2
- ALG6 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 66/689 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0.028); called by muse, mutect2
- ALPK1 | c.1784G>T p.W595L | Missense Mutation (SNP) | VAF 30/610 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2
- ANK3 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 56/642 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ANKRD26 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 21/251 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2
- ANO7 | c.1586T>A p.V529E (on ENST00000274979; = p.V475E on NM_001370694.2) | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ANO7 | c.1765C>A p.L589I (on ENST00000274979; = p.L535I on NM_001370694.2) | Missense Mutation (SNP) | VAF 37/427 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.486); called by muse, mutect2
- ANXA1 | c.1033G>T p.G345* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | called by muse, mutect2, varscan2
- AOC3 | c.2001G>T p.E667D | Missense Mutation (SNP) | VAF 66/461 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- AP3M2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- APLP2 | c.187G>T p.V63L | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.968); called by muse, mutect2
- APOB | c.13672G>A p.E4558K | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- APOB | c.5473G>T p.G1825C | Missense Mutation (SNP) | VAF 55/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARCN1 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 24/544 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2
- ARFGEF2 | c.3509A>T p.E1170V | Missense Mutation (SNP) | VAF 96/825 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARFGEF3 | c.1478G>T p.W493L | Missense Mutation (SNP) | VAF 67/563 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- ARG1 | c.802+1G>A p.X268_splice | Splice Site (SNP) | VAF 22/342 reads (6%) | called by muse, mutect2
- ART5 | c.77T>A p.L26Q | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.02); called by mutect2, varscan2
- ASPM | c.44C>A p.P15Q | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ATP9A | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 26/560 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- ATP9A | c.1059G>T p.M353I | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- BACE2 | c.358G>T p.G120* | Nonsense Mutation (SNP) | VAF 50/602 reads (8%) | called by muse, mutect2
- BHMT2 | c.688G>C p.G230R | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.35); called by muse, mutect2
- BRDT | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 21/147 reads (14%) | called by muse, mutect2, varscan2
- BRK1 | c.174A>T p.E58D | Missense Mutation (SNP) | VAF 27/343 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); called by muse, mutect2
- BTNL9 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- C10orf71 | c.4297G>T p.G1433C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- C16orf54 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 72/782 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.789); called by muse, mutect2
- C1QTNF3 | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2
- C1orf74 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.124); called by muse, mutect2
- C22orf42 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2
- C8A | c.1075A>C p.K359Q | Missense Mutation (SNP) | VAF 52/524 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2
- CACNA1B | c.6956G>T p.G2319V | Missense Mutation (SNP) | VAF 43/284 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CACNA1C | c.1622T>G p.I541S | Missense Mutation (SNP) | VAF 28/306 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.942); called by muse, mutect2
- CACNA1E | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- CALCR | c.1284G>T p.Q428H (on ENST00000649521 / NM_001164737.2; = p.Q412H on NM_001742.4) | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- CATSPER1 | c.389C>T p.S130F | Missense Mutation (SNP) | VAF 22/608 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.081); called by muse, mutect2
- CCDC116 | c.1538G>C p.R513P | Missense Mutation (SNP) | VAF 30/391 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- CCDC142 | c.738G>T p.Q246H | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); called by muse, mutect2
- CCDC18 | c.1676T>A p.L559Q (on ENST00000343253 / NM_001306076.1; = p.L560Q on NM_206886.4) | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC34 | c.466G>T p.E156* | Nonsense Mutation (SNP) | VAF 37/508 reads (7%) | called by muse, mutect2
- CCDC50 | c.640G>T p.D214Y | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- CCIN | c.1242T>A p.D414E | Missense Mutation (SNP) | VAF 41/606 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2
- CDC14A | c.1480G>A p.D494N | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2
- CDHR2 | c.2432C>A p.A811D | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- CDK18 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 19/159 reads (12%) | called by muse, mutect2, varscan2
- CEBPZ | c.2752G>A p.G918R | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- CENPF | c.1293G>T p.M431I | Missense Mutation (SNP) | VAF 25/345 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2
- CEP170 | c.3784G>T p.A1262S | Missense Mutation (SNP) | VAF 106/942 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- CEP41 | c.605G>T p.R202I | Missense Mutation (SNP) | VAF 53/591 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CFAP74 | c.1988T>C p.M663T | Missense Mutation (SNP) | VAF 39/328 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFHR3 | c.739G>T p.G247C | Missense Mutation (SNP) | VAF 97/1075 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CHAF1A | c.2039T>A p.V680D | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- CIC | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 58/457 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- CLSTN2 | c.2291C>A p.A764D | Missense Mutation (SNP) | VAF 48/638 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CNST | c.553G>T p.D185Y | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CNTN2 | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 21/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- CNTNAP2 | c.1004G>T p.G335V | Missense Mutation (SNP) | VAF 99/871 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL11A2 | c.2071-1G>T p.X691_splice (on ENST00000341947 / NM_080680.3; = p.X584_splice on NM_080679.2) | Splice Site (SNP) | VAF 9/188 reads (5%) | called by muse, mutect2
- COL11A2 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- COMTD1 | c.475C>T p.R159W | Missense Mutation (SNP) | VAF 35/212 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CPSF2 | c.556G>T p.G186* | Nonsense Mutation (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- CR2 | c.157G>C p.G53R | Missense Mutation (SNP) | VAF 89/967 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.062); called by muse, mutect2
- CRACD | c.1353C>A p.C451* | Nonsense Mutation (SNP) | VAF 28/385 reads (7%) | called by muse, mutect2
- CRAT | c.650A>T p.Y217F | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2
- CSMD1 | c.5796C>G p.Y1932* (on ENST00000520002; = p.Y1931* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 60/626 reads (10%) | called by muse, mutect2
- CSMD3 | c.515-1G>C p.X172_splice | Splice Site (SNP) | VAF 30/462 reads (6%) | called by muse, mutect2
- CTCFL | c.498C>A p.D166E | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DACT1 | c.1303C>A p.L435M | Missense Mutation (SNP) | VAF 67/618 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.141); called by muse, mutect2, varscan2
- DBR1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 59/811 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCTN1 | c.2579G>T p.G860V | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCTN1 | c.2578G>T p.G860W | Missense Mutation (SNP) | VAF 39/320 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DEFA6 | c.125G>T p.R42L | Missense Mutation (SNP) | VAF 22/376 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.265); called by muse, mutect2
- DEPDC5 | c.1088G>A p.G363D | Missense Mutation (SNP) | VAF 30/553 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DIP2B | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 66/628 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- DLX6 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DMBT1 | c.988G>C p.G330R | Missense Mutation (SNP) | VAF 48/482 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DMBX1 | c.535C>A p.L179I | Missense Mutation (SNP) | VAF 31/235 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- DMD | c.3786A>T p.E1262D | Missense Mutation (SNP) | VAF 20/217 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2
- DNAH17 | c.7198G>T p.D2400Y | Missense Mutation (SNP) | VAF 61/465 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DNAH7 | c.10949G>T p.W3650L | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); called by muse, mutect2
- DNAH9 | c.3133del p.E1045Kfs*41 | Frame Shift Del (DEL) | VAF 69/630 reads (11%) | called by mutect2, pindel, varscan2
- DNAJC30 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- DOCK3 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 38/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- DPY19L2 | c.1586A>T p.Q529L | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DQX1 | c.2079A>C p.E693D | Missense Mutation (SNP) | VAF 28/598 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2
- DRD1 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DSCAML1 | c.6017T>A p.L2006Q (on ENST00000321322; = p.L1946Q on NM_020693.4) | Missense Mutation (SNP) | VAF 50/440 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DTX3L | c.301_307del p.I101Hfs*2 | Frame Shift Del (DEL) | VAF 93/1098 reads (8%) | called by mutect2, pindel
- DYNC1I1 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 43/302 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- ECI2 | c.379C>A p.Q127K (on ENST00000380118 / NM_206836.3; = p.Q97K on NM_006117.2) | Missense Mutation (SNP) | VAF 100/1148 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.005); called by muse, mutect2
- EDN3 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EED | c.461A>T p.Y154F | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EIF4E1B | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- ELAPOR1 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 20/484 reads (4%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.625); called by muse, mutect2
- ELMO1 | c.2073C>A p.S691R | Missense Mutation (SNP) | VAF 89/950 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ELOVL6 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 47/696 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EOGT | c.373A>T p.R125* | Nonsense Mutation (SNP) | VAF 75/772 reads (10%) | called by muse, mutect2
- EPHB3 | c.1599G>T p.Q533H | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.364); called by muse, mutect2
- EPHB4 | c.1072G>C p.A358P | Missense Mutation (SNP) | VAF 44/387 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- EPN1 | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 85/713 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- EPRS1 | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 32/500 reads (6%) | called by muse, mutect2
- ERICH6B | c.1705T>A p.W569R | Missense Mutation (SNP) | VAF 17/491 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EVC2 | c.1186del p.E396Rfs*16 | Frame Shift Del (DEL) | VAF 63/456 reads (14%) | called by mutect2, pindel, varscan2
- FAM171A1 | c.1961G>T p.R654L | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.029); called by muse, mutect2
- FAM171B | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 46/502 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM177B | c.279T>A p.F93L | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.39); PolyPhen benign (0.046); called by muse, mutect2
- FAM240A | c.110G>A p.R37K (on ENST00000444264; = p.R31K on NM_001195442.2) | Missense Mutation (SNP) | VAF 32/507 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.014); called by muse, mutect2
- FAM98A | c.1363G>T p.G455C | Missense Mutation (SNP) | VAF 28/318 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- FANCB | c.815C>G p.T272S | Missense Mutation (SNP) | VAF 37/349 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- FAT1 | c.349A>T p.T117S | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FAT4 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAT4 | c.14779G>T p.A4927S | Missense Mutation (SNP) | VAF 60/546 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- FBXW7 | c.83T>A p.V28E | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.006); called by muse, mutect2
- FCHO1 | c.877G>T p.G293* | Nonsense Mutation (SNP) | VAF 28/180 reads (16%) | called by muse, mutect2, varscan2
- FIGN | c.965A>G p.Y322C | Missense Mutation (SNP) | VAF 55/628 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- FLT4 | c.2230G>T p.G744* | Nonsense Mutation (SNP) | VAF 23/190 reads (12%) | called by muse, mutect2, varscan2
- FMO1 | c.866C>A p.P289Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FREM3 | c.3334C>A p.Q1112K | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- G2E3 | c.1413G>T p.L471F | Missense Mutation (SNP) | VAF 24/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GABBR1 | c.2270A>T p.Q757L | Missense Mutation (SNP) | VAF 44/456 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- GABRA5 | c.200G>T p.G67V | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GABRG2 | c.1253C>A p.P418H (on ENST00000361925 / NM_001375343.1; = p.P378H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/614 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2
- GANAB | c.2180G>T p.R727M | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GARNL3 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 67/426 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GBF1 | c.2642A>C p.K881T (on ENST00000369983 / NM_001377137.1; = p.K880T on NM_004193.3) | Missense Mutation (SNP) | VAF 27/483 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GCKR | c.1120C>A p.Q374K | Missense Mutation (SNP) | VAF 46/756 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- GCKR | c.1121A>G p.Q374R | Missense Mutation (SNP) | VAF 45/754 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2
- GK5 | c.690G>T p.W230C | Missense Mutation (SNP) | VAF 17/342 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GLDC | c.873C>A p.C291* | Nonsense Mutation (SNP) | VAF 90/1128 reads (8%) | called by muse, mutect2
- GLYR1 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.073); called by muse, mutect2
- GMNC | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 34/370 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); called by muse, mutect2
- GNA15 | c.1068C>G p.F356L | Missense Mutation (SNP) | VAF 20/441 reads (5%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); called by muse, mutect2
- GPAT2 | c.1175G>C p.R392T | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.592); called by muse, mutect2
- GPATCH8 | c.2414G>T p.S805I | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.307); called by muse, mutect2
- GPR6 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- GPR85 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.009); called by muse, mutect2
- GRIP1 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 80/791 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRM3 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 47/484 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- GRM8 | c.2280G>T p.M760I | Missense Mutation (SNP) | VAF 36/409 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0.023); called by muse, mutect2
- GRTP1 | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 25/443 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.033); called by muse, mutect2
- GUCY1A1 | c.1354G>T p.D452Y | Missense Mutation (SNP) | VAF 36/742 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- H3C1 | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 41/468 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
- HCN1 | c.1450G>T p.V484L | Missense Mutation (SNP) | VAF 48/1082 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- HEATR1 | c.3071del p.G1024Efs*19 | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | called by mutect2, pindel
- HECW1 | c.1045G>T p.D349Y | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HERC2 | c.6871G>T p.G2291* | Nonsense Mutation (SNP) | VAF 52/1046 reads (5%) | called by muse, mutect2
- HERC5 | c.2760T>A p.F920L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, varscan2
- HERPUD2 | c.617+1G>T p.X206_splice | Splice Site (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- HID1 | c.1984G>T p.A662S | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.077); called by muse, mutect2
- HMGXB3 | c.1822T>A p.S608T (on ENST00000613459; = p.S362T on NM_014983.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/219 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- HMX1 | c.713C>A p.A238D | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- HOXA7 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 44/490 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HOXB6 | c.125C>A p.P42H | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- HPRT1 | c.326A>G p.Q109R | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HSD11B2 | c.694T>A p.Y232N | Missense Mutation (SNP) | VAF 24/361 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HSD3B2 | c.345T>A p.S115R | Missense Mutation (SNP) | VAF 70/671 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HSPG2 | c.9677del p.G3226Dfs*43 | Frame Shift Del (DEL) | VAF 42/390 reads (11%) | called by mutect2, pindel, varscan2
- HTR5A | c.545del p.G182Efs*13 | Frame Shift Del (DEL) | VAF 75/600 reads (13%) | called by mutect2, pindel, varscan2
- IGHV1-46 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 48/854 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2
- IGHV1OR15-9 | c.87G>T p.E29D | Missense Mutation (SNP) | VAF 29/666 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2
- IGKV1D-16 | c.65G>T p.C22F | Missense Mutation (SNP) | VAF 66/996 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.061); called by muse, mutect2
- IGKV6D-21 | c.340C>A p.P114T | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGSF22 | c.1696G>C p.A566P | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL19 | c.157A>T p.T53S | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.087); called by muse, mutect2
- INTS1 | c.1116G>T p.E372D | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- IRS2 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2
- ITGA5 | c.1697G>T p.R566M | Missense Mutation (SNP) | VAF 36/381 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); called by muse, mutect2
- ITGAX | c.1322G>T p.R441M | Missense Mutation (SNP) | VAF 46/383 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ITPR1 | c.1631A>T p.Q544L (on ENST00000354582; = p.Q529L on NM_002222.7) | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- KCNH5 | c.2146C>A p.Q716K | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.101); called by muse, mutect2
- KCNIP1 | c.49del p.Q17Rfs*22 | Frame Shift Del (DEL) | VAF 59/679 reads (9%) | called by mutect2, pindel
- KCTD2 | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KDSR | c.142A>T p.I48F | Missense Mutation (SNP) | VAF 57/488 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- KIAA0319L | c.1798C>G p.Q600E | Missense Mutation (SNP) | VAF 23/299 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- KIAA1549L | c.1057G>T p.E353* (on ENST00000321505; = p.E650* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 44/425 reads (10%) | called by muse, mutect2, varscan2
- KIAA2026 | c.5530G>T p.A1844S | Missense Mutation (SNP) | VAF 32/410 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- KIRREL1 | c.884G>C p.S295T | Missense Mutation (SNP) | VAF 19/678 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); called by muse, mutect2
- KLHL1 | c.1156G>T p.D386Y | Missense Mutation (SNP) | VAF 18/492 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KLHL15 | c.1116dup p.A373Cfs*19 | Frame Shift Ins (INS) | VAF 14/111 reads (13%) | called by mutect2, pindel, varscan2
- KLHL29 | c.890G>C p.R297P | Missense Mutation (SNP) | VAF 15/311 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- KLHL3 | c.937G>A p.A313T | Missense Mutation (SNP) | VAF 31/464 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- KRT4 | c.1514G>T p.S505I | Missense Mutation (SNP) | VAF 62/681 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.16); called by muse, mutect2
- KRTAP20-2 | c.151T>A p.C51S | Missense Mutation (SNP) | VAF 88/842 reads (10%) | PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KRTAP9-9 | c.167G>A p.C56Y | Missense Mutation (SNP) | VAF 76/555 reads (14%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- LAMB1 | c.4190C>A p.T1397N | Missense Mutation (SNP) | VAF 53/397 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.304); called by muse, mutect2, varscan2
- LANCL2 | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 44/436 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.014); called by muse, mutect2
- LARP4B | c.751-1G>T p.X251_splice | Splice Site (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2
- LOXHD1 | c.2848G>C p.D950H | Missense Mutation (SNP) | VAF 114/1077 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- LRP1B | c.6428G>T p.G2143V | Missense Mutation (SNP) | VAF 62/732 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LRRC7 | c.1607G>A p.R536K (on ENST00000651989 / NM_001370785.2; = p.R503K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by muse, mutect2
- MAGEL2 | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- MAGI1 | c.1042G>T p.E348* | Nonsense Mutation (SNP) | VAF 67/678 reads (10%) | called by muse, varscan2
- MAGI2 | c.1606G>T p.V536L | Missense Mutation (SNP) | VAF 121/967 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MBL2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 67/741 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2
- MCF2L | c.574G>C p.V192L (on ENST00000375608; = p.V160L on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.246); called by muse, mutect2
- MCOLN1 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 119/1015 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MED12L | c.904C>A p.L302I | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- MEGF11 | c.376G>T p.G126W | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MEIS2 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 28/395 reads (7%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.19); called by muse, mutect2
- MEP1B | c.2059A>G p.S687G | Missense Mutation (SNP) | VAF 67/618 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- METAP1D | c.865G>T p.E289* | Nonsense Mutation (SNP) | VAF 40/438 reads (9%) | called by muse, mutect2
- MGAM2 | c.2687T>G p.L896R | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MKRN2OS | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 107/1024 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MMP1 | c.974C>A p.P325Q | Missense Mutation (SNP) | VAF 49/846 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MMP8 | c.478A>G p.I160V | Missense Mutation (SNP) | VAF 36/274 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- MPEG1 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 48/501 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MRC1 | c.1407G>T p.K469N | Missense Mutation (SNP) | VAF 51/362 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MRC2 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 46/353 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MUC16 | c.29497G>T p.D9833Y | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.534); called by muse, mutect2
- MUC17 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MUC5AC | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 49/364 reads (13%) | SIFT tolerated (0.32); called by muse, mutect2, varscan2
- MYO18B | c.1205C>A p.S402Y | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.471); called by muse, mutect2
- MYRFL | c.904-2A>T p.X302_splice | Splice Site (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2, varscan2
- MYT1L | c.3409C>T p.H1137Y | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- NAA40 | c.73G>T p.V25F | Missense Mutation (SNP) | VAF 62/566 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- NALCN | c.1191C>A p.D397E | Missense Mutation (SNP) | VAF 27/644 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2
- NBPF15 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 99/1300 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- NCAPG2 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOR1 | c.2977C>G p.P993A | Missense Mutation (SNP) | VAF 20/586 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2
- NDRG2 | c.543G>T p.W181C (on ENST00000298687 / NM_001354570.1; = p.W167C on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/408 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- NEPRO | c.233G>T p.R78L | Missense Mutation (SNP) | VAF 46/408 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- NGDN | c.929G>A p.G310D | Missense Mutation (SNP) | VAF 42/807 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- NGLY1 | c.1880G>T p.W627L | Missense Mutation (SNP) | VAF 49/633 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NKD1 | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.295); called by muse, mutect2
- NLRP2 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 111/826 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP5 | c.1051A>T p.M351L | Missense Mutation (SNP) | VAF 24/183 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- NOTCH4 | c.4429G>T p.E1477* | Nonsense Mutation (SNP) | VAF 28/251 reads (11%) | called by muse, mutect2, varscan2
- NOTCH4 | c.3882del p.S1296Pfs*8 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | called by mutect2, pindel, varscan2
- NPR1 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPR3 | c.1115T>A p.L372Q | Missense Mutation (SNP) | VAF 33/617 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRAP | c.2421C>G p.F807L (on ENST00000359988 / NM_001322945.2; = p.F772L on NM_006175.4) | Missense Mutation (SNP) | VAF 30/430 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- NUGGC | c.2036G>T p.G679V | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- NUP205 | c.4075G>T p.V1359F | Missense Mutation (SNP) | VAF 92/946 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2
- NXT2 | c.298G>T p.V100L (on ENST00000372106 / NM_001242617.2; = p.V155L on NM_018698.5) | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- OR10A5 | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 64/561 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR13J1 | c.29C>A p.S10Y | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.08); called by muse, mutect2
- OR14I1 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 32/289 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR1N1 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 93/472 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- OR2F1 | c.148A>T p.R50* | Nonsense Mutation (SNP) | VAF 27/463 reads (6%) | called by muse, mutect2
- OR2J2 | c.61T>A p.W21R | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.169); called by muse, mutect2
- OR2L5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2
- OR4K13 | c.461T>A p.V154E | Missense Mutation (SNP) | VAF 24/584 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- OR51T1 | c.674G>C p.R225P | Missense Mutation (SNP) | VAF 32/342 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- OR56A3 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OR6N1 | c.885G>T p.K295N | Missense Mutation (SNP) | VAF 24/246 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.343); called by muse, mutect2
- OTOG | c.6374G>A p.G2125E | Missense Mutation (SNP) | VAF 17/456 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OXCT1 | c.1257G>T p.M419I | Missense Mutation (SNP) | VAF 44/1065 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- PAPPA | c.218G>C p.R73P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- PCDHA7 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 57/743 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- PCDHB16 | c.1534C>A p.H512N | Missense Mutation (SNP) | VAF 10/355 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.108); called by muse, mutect2
- PCDHB5 | c.2145G>T p.R715S | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PCDHB7 | c.1033C>A p.P345T | Missense Mutation (SNP) | VAF 17/157 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA5 | c.1646G>A p.S549N | Missense Mutation (SNP) | VAF 79/675 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PCLO | c.4471A>C p.K1491Q | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2
- PDZD4 | c.1000C>A p.L334M | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PEAK1 | c.4345G>T p.G1449* | Nonsense Mutation (SNP) | VAF 89/558 reads (16%) | called by muse, mutect2, varscan2
- PIWIL1 | c.48G>T p.Q16H | Missense Mutation (SNP) | VAF 79/642 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- PLCB1 | c.3613G>T p.G1205* | Nonsense Mutation (SNP) | VAF 60/507 reads (12%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.3145C>T p.P1049S | Missense Mutation (SNP) | VAF 54/340 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLN | c.547G>T p.G183C | Missense Mutation (SNP) | VAF 28/572 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.078); called by muse, mutect2
- POLR2B | c.2012A>G p.E671G | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- POU3F1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 15/425 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PPAT | c.129-2A>T p.X43_splice | Splice Site (SNP) | VAF 18/278 reads (6%) | called by muse, mutect2
- PPFIA2 | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 59/578 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- PPM1K | c.57G>C p.R19S | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2
- PPM1L | c.319G>T p.D107Y | Missense Mutation (SNP) | VAF 50/442 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PPP1R42 | c.866T>C p.L289S | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.081); called by muse, mutect2
- PRAMEF19 | c.864C>A p.I288= | Splice Region (SNP) | VAF 69/608 reads (11%) | called by muse, mutect2, varscan2
- PRDM13 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- PRDM9 | c.1293C>A p.C431* | Nonsense Mutation (SNP) | VAF 141/1346 reads (10%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.212_215del p.S71Mfs*63 | Frame Shift Del (DEL) | VAF 53/479 reads (11%) | called by mutect2, pindel, varscan2
- PSCA | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 57/547 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PTPN13 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 28/656 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RAD54L2 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 139/1041 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASAL2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 30/293 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.19); called by muse, mutect2
- RASAL2 | c.1184G>T p.G395V | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASGRP4 | c.520G>C p.G174R | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RASL11B | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2
- RASSF8 | c.366G>C p.R122S | Missense Mutation (SNP) | VAF 86/575 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- RC3H1 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RECQL | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 18/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RELN | c.656G>T p.W219L | Missense Mutation (SNP) | VAF 38/487 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); called by muse, mutect2
- RHBDF2 | c.2282T>C p.I761T | Missense Mutation (SNP) | VAF 91/741 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RMDN3 | c.566C>T p.S189F | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2
- RORA | c.1146T>A p.D382E (on ENST00000335670 / NM_134261.3; = p.D407E on NM_002943.3) | Missense Mutation (SNP) | VAF 64/708 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.007); called by muse, mutect2
- RPTN | c.908A>T p.Q303L | Missense Mutation (SNP) | VAF 96/1022 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.105); called by muse, mutect2
- RSPRY1 | c.973A>C p.N325H | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.297); called by muse, mutect2
- RTCA | c.312G>C p.Q104H | Missense Mutation (SNP) | VAF 49/576 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RTN1 | c.317C>A p.T106K | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RTN4R | c.605A>C p.H202P | Missense Mutation (SNP) | VAF 42/826 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2
- SAP30BP | c.829A>T p.T277S | Missense Mutation (SNP) | VAF 123/673 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SCAPER | c.3729G>C p.L1243F | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- SCN8A | c.3596G>T p.W1199L | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- SDCCAG8 | c.308G>T p.R103M | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SEC24C | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 60/389 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- SELE | c.1177_1178insAG p.S393Kfs*13 | Frame Shift Ins (INS) | VAF 56/725 reads (8%) | called by muse*, mutect2
- SELE | c.1175_1176del p.S392* | Frame Shift Del (DEL) | VAF 55/741 reads (7%) | called by muse*, mutect2
- SERPINB13 | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 51/457 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- SEZ6L2 | c.1638C>G p.S546R (on ENST00000308713 / NM_001114099.3; = p.S476R on NM_012410.4) | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2
- SGIP1 | c.1240C>A p.P414T | Missense Mutation (SNP) | VAF 31/349 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2
- SH3GL2 | c.988G>T p.G330W | Missense Mutation (SNP) | VAF 40/254 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHROOM3 | c.3911G>C p.C1304S | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.53); PolyPhen benign (0.189); called by muse, mutect2
- SIPA1L1 | c.2420G>C p.R807P | Missense Mutation (SNP) | VAF 26/488 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC25A18 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 18/348 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.803); called by muse, mutect2
- SLC5A11 | c.1126C>A p.L376M | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC5A8 | c.991C>A p.L331M | Missense Mutation (SNP) | VAF 53/440 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- SLC5A9 | c.1222C>A p.L408M | Missense Mutation (SNP) | VAF 46/686 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- SLC8A2 | c.706T>A p.F236I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, varscan2
- SLC9A9 | c.1151T>A p.L384Q | Missense Mutation (SNP) | VAF 47/543 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- SLC9A9 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 100/1058 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMC3 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 26/578 reads (4%) | called by muse, mutect2
- SOWAHB | c.1123G>T p.G375W | Missense Mutation (SNP) | VAF 17/284 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2
- SOX11 | c.769C>A p.Q257K | Missense Mutation (SNP) | VAF 46/345 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.037); called by muse, varscan2
- SPANXN3 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA7 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 24/405 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.036); called by muse, mutect2
- SPTAN1 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 52/898 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- SSH2 | c.1344A>C p.A448= | Splice Region (SNP) | VAF 34/342 reads (10%) | called by muse, mutect2, varscan2
- STAB2 | c.1784C>A p.T595N | Missense Mutation (SNP) | VAF 78/691 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- SUPT20HL1 | c.1847del p.P616Qfs*60 | Frame Shift Del (DEL) | VAF 20/216 reads (9%) | called by mutect2, pindel
- SYT13 | c.508T>G p.C170G | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- TARS1 | c.344A>T p.D115V | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- TBC1D22B | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 58/634 reads (9%) | SIFT tolerated (0.93); PolyPhen benign (0.007); called by muse, mutect2
- TBC1D31 | c.1084A>T p.S362C | Missense Mutation (SNP) | VAF 107/509 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- TCHH | c.3709G>C p.D1237H | Missense Mutation (SNP) | VAF 99/940 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TDP1 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 31/662 reads (5%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.063); called by muse, mutect2
- TEX13C | c.1447A>T p.S483C | Missense Mutation (SNP) | VAF 66/354 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- TFG | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TGFBR3 | c.893A>T p.N298I | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2
- THSD7A | c.1847G>T p.C616F | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TICRR | c.2419G>A p.D807N | Missense Mutation (SNP) | VAF 152/1002 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- TMEM121B | c.965C>A p.S322Y | Missense Mutation (SNP) | VAF 21/397 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.236); called by muse, mutect2
- TMEM132C | c.1593G>T p.E531D | Missense Mutation (SNP) | VAF 89/626 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- TMPRSS15 | c.1686G>T p.K562N | Missense Mutation (SNP) | VAF 21/157 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- TPO | c.506C>A p.S169Y | Missense Mutation (SNP) | VAF 26/764 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TRIM28 | c.715G>T p.D239Y | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM42 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 51/628 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.164); called by muse, mutect2
- TRIM58 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- TRO | c.3346G>T p.A1116S | Missense Mutation (SNP) | VAF 30/263 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- TRPA1 | c.2174C>A p.S725Y | Missense Mutation (SNP) | VAF 35/339 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- TRPC4AP | c.1325A>T p.H442L | Missense Mutation (SNP) | VAF 23/374 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.022); called by muse, mutect2
- TRPM2 | c.4009G>C p.G1337R | Missense Mutation (SNP) | VAF 21/215 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSC2 | c.3934G>T p.V1312L | Missense Mutation (SNP) | VAF 43/361 reads (12%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTC22 | c.688A>T p.T230S | Missense Mutation (SNP) | VAF 65/740 reads (9%) | SIFT tolerated (0.53); PolyPhen benign (0.275); called by muse, mutect2
- TTK | c.905C>T p.S302F | Missense Mutation (SNP) | VAF 38/360 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2
- TUBA3D | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.174); called by muse, mutect2
- TXNL1 | c.322G>T p.E108* | Nonsense Mutation (SNP) | VAF 22/238 reads (9%) | called by muse, mutect2
- UBN2 | c.3481A>T p.N1161Y | Missense Mutation (SNP) | VAF 62/748 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); called by muse, mutect2
- UBTF | c.2287T>A p.S763T | Missense Mutation (SNP) | VAF 75/475 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- UBTFL1 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by mutect2, varscan2
- UBXN4 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 46/704 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.116); called by muse, mutect2
- UMOD | c.1478G>T p.G493V | Missense Mutation (SNP) | VAF 28/596 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.544); called by muse, mutect2
- USP35 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP46 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); called by muse, mutect2
- USP5 | c.854A>T p.K285M | Missense Mutation (SNP) | VAF 60/416 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- VAV1 | c.1955G>T p.C652F | Missense Mutation (SNP) | VAF 26/462 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); called by muse, mutect2
- VILL | c.135+3G>C | Splice Region (SNP) | VAF 26/273 reads (10%) | called by muse, mutect2, varscan2
- VN1R5 | c.838A>G p.T280A | Missense Mutation (SNP) | VAF 48/466 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VPS35L | c.2023A>T p.I675F | Missense Mutation (SNP) | VAF 59/649 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- WDFY4 | c.3058C>A p.P1020T | Missense Mutation (SNP) | VAF 52/428 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WDR33 | c.1102G>T p.G368C | Missense Mutation (SNP) | VAF 42/553 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR87 | c.7334C>T p.P2445L | Missense Mutation (SNP) | VAF 21/232 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- WFDC2 | c.293A>T p.Q98L | Missense Mutation (SNP) | VAF 57/519 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- WNK4 | c.1328C>A p.A443E | Missense Mutation (SNP) | VAF 88/659 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- WNT16 | c.930C>A p.C310* (on ENST00000222462 / NM_057168.2; = p.C300* on NM_016087.2) | Nonsense Mutation (SNP) | VAF 67/569 reads (12%) | called by muse, mutect2, varscan2
- WWC1 | c.407A>G p.E136G | Missense Mutation (SNP) | VAF 43/341 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- XIRP2 | c.1937A>T p.K646I (on ENST00000628543; = p.K821I on NM_152381.6) | Missense Mutation (SNP) | VAF 27/245 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XIRP2 | c.4671G>T p.R1557S (on ENST00000628543; = p.R1732S on NM_152381.6) | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.194); called by muse, mutect2
- XYLT1 | c.2714G>T p.W905L | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.022); called by muse, mutect2
- YLPM1 | c.5431G>T p.E1811* | Nonsense Mutation (SNP) | VAF 30/699 reads (4%) | called by muse, mutect2
- ZDBF2 | c.946C>A p.P316T | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2
- ZDHHC23 | c.556C>T p.H186Y | Missense Mutation (SNP) | VAF 74/758 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZEB2 | c.2629A>T p.N877Y | Missense Mutation (SNP) | VAF 40/489 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2
- ZNF224 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 38/466 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF33B | c.102G>T p.R34S | Missense Mutation (SNP) | VAF 44/555 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- ZNF512B | c.626C>A p.P209H | Missense Mutation (SNP) | VAF 45/374 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF646 | c.3561G>T p.E1187D | Missense Mutation (SNP) | VAF 17/150 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF728 | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.302); called by muse, varscan2
- ZNF728 | c.479C>A p.S160* | Nonsense Mutation (SNP) | VAF 38/276 reads (14%) | called by muse, varscan2
- ZNF845 | c.2024A>T p.K675M | Missense Mutation (SNP) | VAF 90/728 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- ZNF99 | c.1822C>A p.L608I | Missense Mutation (SNP) | VAF 70/774 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ZP3 | c.256A>T p.T86S (on ENST00000394857 / NM_001110354.2; = p.T35S on NM_007155.6) | Missense Mutation (SNP) | VAF 34/241 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZP4 | c.1174G>T p.G392* | Nonsense Mutation (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- ABCC8 | c.1596C>T p.S532= | Silent (SNP) | VAF 30/522 reads (6%) | catalogued as rs761871453, COSV100217938; called by muse, mutect2
- ADCY8 | c.2364C>A p.I788= | Silent (SNP) | VAF 76/908 reads (8%) | called by muse, mutect2
- ADCY8 | c.2253G>T p.L751= | Silent (SNP) | VAF 67/732 reads (9%) | called by muse, mutect2
- ADD3 | c.1726C>T p.L576= | Silent (SNP) | VAF 33/258 reads (13%) | called by muse, mutect2, varscan2
- ADGB | c.2802A>G p.K934= | Silent (SNP) | VAF 20/143 reads (14%) | called by muse, mutect2, varscan2
- ADGRF3 | c.2487C>A p.A829= (on ENST00000311519 / NM_001145168.1; = p.A630= on NM_153835.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/293 reads (5%) | called by muse, mutect2
- ADGRG4 | c.8623C>T p.L2875= | Silent (SNP) | VAF 34/251 reads (14%) | catalogued as COSV99795775; called by muse, mutect2, varscan2
- ADGRL2 | c.1137G>T p.V379= | Silent (SNP) | VAF 27/308 reads (9%) | called by muse, mutect2
- AHNAK2 | c.6783C>A p.P2261= | Silent (SNP) | VAF 78/736 reads (11%) | called by muse, mutect2, varscan2
- AHSG | c.594T>C p.Y198= | Silent (SNP) | VAF 38/354 reads (11%) | catalogued as COSV56607891; called by muse, mutect2, varscan2
- ALS2 | c.1167C>T p.T389= | Silent (SNP) | VAF 20/449 reads (4%) | called by muse, mutect2
- AOC1 | c.1680C>A p.S560= | Silent (SNP) | VAF 55/486 reads (11%) | catalogued as COSV100710848; called by muse, mutect2, varscan2
- APP | c.1725C>T p.D575= | Silent (SNP) | VAF 60/967 reads (6%) | catalogued as rs748630651, COSV100695747; called by muse, mutect2
- ARHGAP5 | c.3108G>T p.V1036= | Silent (SNP) | VAF 49/349 reads (14%) | called by muse, mutect2, varscan2
- ARHGEF18 | c.813C>T p.R271= (on ENST00000359920 / NM_001130955.2; = p.R167= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 36/409 reads (9%) | catalogued as COSV60470652; called by muse, mutect2
- ASTL | c.1149G>A p.Q383= | Silent (SNP) | VAF 56/642 reads (9%) | called by muse, mutect2
- ATF2 | c.1152T>G p.A384= | Silent (SNP) | VAF 63/547 reads (12%) | called by muse, mutect2, varscan2
- ATF2 | c.354C>T p.I118= | Silent (SNP) | VAF 25/419 reads (6%) | called by muse, mutect2
- ATP1A3 | c.786G>A p.V262= (on ENST00000545399 / NM_001256214.2; = p.V249= on NM_152296.5) | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs1568864760; called by muse, mutect2, varscan2
- BICRA | c.669G>T p.G223= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- C6 | c.36G>T p.L12= | Silent (SNP) | VAF 72/715 reads (10%) | called by muse, mutect2, varscan2
- CAND2 | c.1815G>T p.R605= (on ENST00000456430 / NM_001162499.2; = p.R512= on NM_012298.3) | Silent (SNP) | VAF 28/213 reads (13%) | called by muse, mutect2, varscan2
- CCDC168 | c.4044G>A p.V1348= | Silent (SNP) | VAF 18/285 reads (6%) | catalogued as COSV70554591; called by muse, mutect2
- CD2 | c.1047C>A p.S349= | Silent (SNP) | VAF 6/106 reads (6%) | catalogued as COSV65644148; called by muse, mutect2
- CDH6 | c.927C>T p.D309= | Silent (SNP) | VAF 33/356 reads (9%) | catalogued as rs149429954; called by muse, mutect2
- CHRM3 | c.1302C>A p.A434= | Silent (SNP) | VAF 64/802 reads (8%) | called by muse, mutect2
- CLDN18 | c.9C>A p.T3= | Silent (SNP) | VAF 6/95 reads (6%) | called by muse, mutect2
- CNTN2 | c.717C>G p.P239= | Silent (SNP) | VAF 21/506 reads (4%) | called by muse, mutect2
- CNTNAP2 | c.2811C>A p.I937= | Silent (SNP) | VAF 149/937 reads (16%) | catalogued as COSV100668692; called by muse, mutect2, varscan2
- CPN1 | c.270G>T p.A90= | Silent (SNP) | VAF 33/482 reads (7%) | catalogued as rs759014388, COSV64942217; called by muse, mutect2
- CREG2 | c.39G>T p.G13= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- CSMD1 | c.6480C>A p.S2160= (on ENST00000520002; = p.S2159= on NM_033225.6) | Silent (SNP) | VAF 20/326 reads (6%) | called by muse, mutect2
- CSMD1 | c.4200T>C p.N1400= (on ENST00000520002; = p.N1399= on NM_033225.6) | Silent (SNP) | VAF 19/204 reads (9%) | catalogued as rs1031205038; called by muse, mutect2
- CTNNA2 | c.816C>A p.G272= | Silent (SNP) | VAF 30/343 reads (9%) | catalogued as rs1040206412, COSV63556127; called by muse, mutect2
- CYP26B1 | c.594G>T p.L198= | Silent (SNP) | VAF 16/308 reads (5%) | called by muse, mutect2
- DDC | c.84G>A p.Q28= | Silent (SNP) | VAF 54/1070 reads (5%) | called by muse, mutect2
- DLG4 | c.984G>T p.V328= (on ENST00000399506 / NM_001321075.3; = p.V371= on NM_001365.4) | Silent (SNP) | VAF 57/466 reads (12%) | called by muse, mutect2, varscan2
- DMRTB1 | c.445C>A p.R149= | Silent (SNP) | VAF 21/175 reads (12%) | called by muse, mutect2, varscan2
- DNAH8 | c.6294A>T p.I2098= | Silent (SNP) | VAF 69/606 reads (11%) | called by muse, mutect2, varscan2
- DNAI2 | c.1815C>A p.A605= | Silent (SNP) | VAF 40/731 reads (5%) | called by muse, mutect2
- EPB41L2 | c.2757G>T p.S919= | Silent (SNP) | VAF 37/414 reads (9%) | catalogued as rs779533012; called by muse, mutect2
- EPHB1 | c.1791C>T p.P597= | Silent (SNP) | VAF 57/708 reads (8%) | called by muse, mutect2
- FAM120B | c.2388G>T p.T796= | Silent (SNP) | VAF 113/1148 reads (10%) | catalogued as COSV99379217; called by muse, mutect2
- FAM71B | c.1515C>A p.T505= | Silent (SNP) | VAF 57/501 reads (11%) | called by muse, mutect2, varscan2
- FBXL16 | c.105C>T p.I35= | Silent (SNP) | VAF 28/172 reads (16%) | called by muse, mutect2, varscan2
- FBXL18 | c.54A>C p.A18= | Silent (SNP) | VAF 22/339 reads (6%) | called by muse, mutect2
- FECH | c.1044G>C p.L348= | Silent (SNP) | VAF 41/502 reads (8%) | called by muse, mutect2
- FIGNL2 | c.1542C>A p.L514= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- FMO2 | c.879C>A p.L293= | Silent (SNP) | VAF 40/298 reads (13%) | catalogued as COSV99269191; called by muse, mutect2, varscan2
- FMR1 | c.351C>A p.P117= | Silent (SNP) | VAF 24/230 reads (10%) | catalogued as rs782492689; called by muse, mutect2, varscan2
- FRMPD1 | c.1755C>A p.A585= | Silent (SNP) | VAF 31/207 reads (15%) | called by muse, mutect2, varscan2
- FSHR | c.1128C>A p.A376= | Silent (SNP) | VAF 65/775 reads (8%) | catalogued as COSV58617547; called by muse, mutect2
- FTHL17 | c.309C>G p.S103= | Silent (SNP) | VAF 15/92 reads (16%) | called by muse, mutect2, varscan2
- FZD8 | c.1419G>T p.V473= | Silent (SNP) | VAF 38/380 reads (10%) | called by muse, mutect2, varscan2
- GABRA6 | c.1158G>A p.E386= | Silent (SNP) | VAF 62/496 reads (13%) | called by muse, mutect2, varscan2
- GJB4 | c.222G>T p.V74= | Silent (SNP) | VAF 30/443 reads (7%) | catalogued as COSV100258344; called by muse, mutect2
- GLIS3 | c.621G>T p.P207= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV60933505; called by muse, mutect2, varscan2
- GRIN2C | c.1456C>A p.R486= | Silent (SNP) | VAF 53/344 reads (15%) | called by muse, mutect2, varscan2
- GRM1 | c.177C>A p.A59= | Silent (SNP) | VAF 72/497 reads (14%) | catalogued as COSV51395951; called by muse, mutect2, varscan2
- GRM1 | c.477G>T p.V159= | Silent (SNP) | VAF 89/582 reads (15%) | catalogued as COSV99268394; called by muse, mutect2, varscan2
- GRM3 | c.1743C>A p.V581= | Silent (SNP) | VAF 33/400 reads (8%) | called by muse, mutect2
- HDAC9 | c.3066C>A p.G1022= (on ENST00000441542 / NM_178425.3; = p.G1019= on NM_178423.3) | Silent (SNP) | VAF 62/636 reads (10%) | catalogued as rs956780555, COSV67782078; called by muse, mutect2
- HDX | c.1380C>T p.S460= | Silent (SNP) | VAF 52/372 reads (14%) | called by muse, mutect2, varscan2
- HELZ | c.252G>T p.L84= | Silent (SNP) | VAF 65/383 reads (17%) | called by muse, mutect2, varscan2
- HHLA1 | c.180G>A p.V60= | Silent (SNP) | VAF 68/778 reads (9%) | catalogued as rs1358994256; called by muse, mutect2
- HOXA13 | c.990C>G p.T330= | Silent (SNP) | VAF 56/871 reads (6%) | called by muse, mutect2
- HOXA4 | c.930G>T p.P310= | Silent (SNP) | VAF 30/257 reads (12%) | called by muse, mutect2, varscan2
- HTR5A | c.1011C>A p.I337= | Silent (SNP) | VAF 36/402 reads (9%) | called by muse, mutect2
- IGKV6D-21 | c.90G>A p.Q30= | Silent (SNP) | VAF 29/226 reads (13%) | called by mutect2, varscan2
- IGSF1 | c.3582A>G p.L1194= | Silent (SNP) | VAF 82/400 reads (21%) | called by muse, mutect2, varscan2
- ILDR2 | c.1821C>T p.G607= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as COSV99612979; called by muse, mutect2
- IQSEC1 | c.975G>T p.P325= | Silent (SNP) | VAF 24/217 reads (11%) | catalogued as rs544776500, COSV56220961; called by muse, mutect2
- ITCH | c.2511G>A p.L837= (on ENST00000262650 / NM_001257137.3; = p.L796= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/717 reads (10%) | called by muse, mutect2, varscan2
- ITGA8 | c.1500C>A p.I500= | Silent (SNP) | VAF 47/387 reads (12%) | catalogued as COSV65236707; called by muse, mutect2, varscan2
- ITGAX | c.1866G>A p.G622= | Silent (SNP) | VAF 40/328 reads (12%) | catalogued as rs749117948; called by muse, mutect2, varscan2
- KCNA4 | c.1749A>C p.A583= | Silent (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- KDM1A | c.561G>T p.R187= | Silent (SNP) | VAF 20/420 reads (5%) | called by muse, mutect2
- KLK11 | c.726C>T p.N242= (on ENST00000594768 / NM_144947.3; = p.N210= on NM_006853.3) | Silent (SNP) | VAF 58/552 reads (11%) | called by muse, mutect2, varscan2
- KRTAP9-1 | c.84T>A p.T28= | Silent (SNP) | VAF 63/535 reads (12%) | called by muse, mutect2, varscan2
- LRP2 | c.1668G>T p.L556= | Silent (SNP) | VAF 37/937 reads (4%) | called by muse, mutect2
- LRRC1 | c.1296T>C p.C432= | Silent (SNP) | VAF 33/527 reads (6%) | called by muse, mutect2
- LRRC38 | c.549G>T p.L183= | Silent (SNP) | VAF 20/290 reads (7%) | called by muse, mutect2
- LRRC72 | c.795A>T p.T265= | Silent (SNP) | VAF 40/468 reads (9%) | called by muse, mutect2
- LRRIQ1 | c.1824A>T p.S608= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- METAP1D | c.864G>T p.T288= | Silent (SNP) | VAF 40/431 reads (9%) | catalogued as COSV59930127; called by muse, mutect2
- MMRN1 | c.3636C>A p.A1212= | Silent (SNP) | VAF 13/179 reads (7%) | called by muse, mutect2
- MRE11 | c.780G>C p.L260= | Silent (SNP) | VAF 22/623 reads (4%) | catalogued as rs1278688194; called by muse, mutect2
- MUC16 | c.26073T>A p.T8691= | Silent (SNP) | VAF 25/200 reads (13%) | called by muse, mutect2, varscan2
- MUC16 | c.17436T>A p.T5812= | Silent (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- MUC16 | c.1800C>A p.T600= | Silent (SNP) | VAF 50/344 reads (15%) | called by muse, mutect2, varscan2
- MYH4 | c.1551G>T p.G517= | Silent (SNP) | VAF 92/869 reads (11%) | called by muse, mutect2, varscan2
- MYH6 | c.4014C>A p.A1338= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- MYL7 | c.156C>A p.I52= | Silent (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- MYPN | c.2304C>A p.P768= | Silent (SNP) | VAF 94/1134 reads (8%) | called by muse, mutect2
- NALCN | c.2034G>C p.L678= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- NAPRT | c.750G>A p.L250= | Silent (SNP) | VAF 35/257 reads (14%) | called by muse, mutect2, varscan2
- NID1 | c.384C>T p.P128= | Silent (SNP) | VAF 16/334 reads (5%) | called by muse, mutect2
- NLRP5 | c.1975C>T p.L659= | Silent (SNP) | VAF 35/266 reads (13%) | catalogued as rs755157047; called by muse, mutect2, varscan2
- NPR1 | c.495G>T p.L165= | Silent (SNP) | VAF 18/142 reads (13%) | called by mutect2, varscan2
- NPTX2 | c.234C>G p.G78= | Silent (SNP) | VAF 23/156 reads (15%) | called by muse, mutect2, varscan2
- NRN1 | c.195G>A p.V65= | Silent (SNP) | VAF 13/161 reads (8%) | called by muse, mutect2
- NRXN1 | c.3459C>A p.A1153= | Silent (SNP) | VAF 59/668 reads (9%) | called by muse, mutect2
- NTN1 | c.1347C>A p.A449= | Silent (SNP) | VAF 29/213 reads (14%) | called by muse, mutect2, varscan2
- NUP205 | c.399T>C p.L133= | Silent (SNP) | VAF 38/537 reads (7%) | called by muse, mutect2
- OR10A3 | c.192G>T p.L64= | Silent (SNP) | VAF 28/266 reads (11%) | called by muse, mutect2
- OR10T2 | c.687C>A p.I229= | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as rs762460386, COSV100555052; called by muse, mutect2
- OR2G6 | c.570G>T p.V190= | Silent (SNP) | VAF 36/362 reads (10%) | catalogued as COSV58575003; called by muse, mutect2
- OR2L3 | c.141C>A p.L47= | Silent (SNP) | VAF 34/667 reads (5%) | catalogued as rs752247542, COSV63455089; called by muse, mutect2
- OR2L8 | c.124C>T p.L42= | Silent (SNP) | VAF 34/594 reads (6%) | called by muse, mutect2
- OR4A5 | c.39G>T p.L13= | Silent (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- OR51A4 | c.96C>A p.P32= | Silent (SNP) | VAF 29/349 reads (8%) | catalogued as COSV66749897; called by muse, mutect2
- OR5D14 | c.732C>A p.A244= | Silent (SNP) | VAF 29/253 reads (11%) | called by muse, mutect2, varscan2
- OR5L1 | c.786C>A p.P262= | Silent (SNP) | VAF 62/577 reads (11%) | called by muse, mutect2, varscan2
- OSTF1 | c.318A>G p.G106= | Silent (SNP) | VAF 55/510 reads (11%) | called by muse, mutect2, varscan2
- OTOP2 | c.759C>T p.F253= | Silent (SNP) | VAF 34/362 reads (9%) | catalogued as rs772775488; called by muse, mutect2
- PBRM1 | c.3081A>T p.P1027= (on ENST00000296302 / NM_001366071.2; = p.P1002= on NM_018313.5) | Silent (SNP) | VAF 54/404 reads (13%) | called by muse, varscan2
- PC | c.657G>T p.R219= | Silent (SNP) | VAF 65/725 reads (9%) | called by muse, mutect2
- PCDH11X | c.2430T>C p.Y810= | Silent (SNP) | VAF 80/526 reads (15%) | called by muse, mutect2, varscan2
- PCDH15 | c.3549C>G p.L1183= | Silent (SNP) | VAF 66/636 reads (10%) | called by muse, mutect2, varscan2
- PCDHB12 | c.1773G>T p.A591= | Silent (SNP) | VAF 55/653 reads (8%) | catalogued as rs782177865, COSV53396124; called by muse, mutect2
- PCK1 | c.744C>A p.L248= | Silent (SNP) | VAF 42/403 reads (10%) | called by muse, mutect2, varscan2
- PCMTD1 | c.873G>T p.V291= | Silent (SNP) | VAF 21/217 reads (10%) | catalogued as COSV62125126; called by muse, mutect2, varscan2
- PCOLCE2 | c.1159C>A p.R387= | Silent (SNP) | VAF 84/960 reads (9%) | called by muse, mutect2
- PIK3C2B | c.786G>C p.P262= | Silent (SNP) | VAF 20/239 reads (8%) | catalogued as COSV65803696, COSV65804342; called by muse, mutect2
- PJA1 | c.327C>T p.S109= | Silent (SNP) | VAF 54/312 reads (17%) | called by muse, mutect2, varscan2
- PLEC | c.7053G>T p.A2351= (on ENST00000322810 / NM_201380.4; = p.A2241= on NM_000445.5) | Silent (SNP) | VAF 49/407 reads (12%) | catalogued as COSV59700476; called by muse, mutect2, varscan2
169 further variants in this file (0 protein-altering or splice-affecting, 65 silent, 104 other) are not listed here.
